Somatic mutation profile of tumor specimen 0DF3ID from CCDI case PBBPDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.9 years (4,727 days).
Specimen 0DF3ID: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cce12ef0-4a7b-4f55-8372-c4e09a6f010d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DF3IV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89130008-7be9-4a0b-a925-f05981d31bf3

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Intron 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 380/755 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, varscan2
- TP53 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 308/716 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as rs55832599, CM120851, COSV52678166, COSV52736883, COSV52827473; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ITGA8 | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 436/1031 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs150974250; called by muse, varscan2
- KCTD16 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 358/719 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs773343153, COSV72577989; called by muse, varscan2
- LRRFIP2 | c.764G>A p.R255H | Missense Mutation (SNP) | VAF 384/874 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs776256882; called by muse, varscan2
- SUZ12 | c.1237A>T p.R413* | Nonsense Mutation (SNP) | VAF 68/695 reads (10%) | catalogued as COSV59501745; called by muse, varscan2
- UNC45B | c.2245C>T p.R749W | Missense Mutation (SNP) | VAF 241/616 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.613); catalogued as rs746256786; called by muse, varscan2
- BARHL2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 260/586 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, varscan2
- DDX3X | c.148+1G>T p.X50_splice (on ENST00000399959; = p.X51_splice on NM_001356.5) | Splice Site (SNP) | VAF 309/326 reads (95%) | called by muse, varscan2
- NIN | c.5645C>T p.S1882F (on ENST00000382041 / NM_182946.1; = p.S1169F on NM_016350.4) | Missense Mutation (SNP) | VAF 310/684 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- OR2J3 | c.889A>G p.N297D | Missense Mutation (SNP) | VAF 432/482 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, varscan2
- POLI | c.1073G>T p.C358F | Missense Mutation (SNP) | VAF 298/678 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.244); called by muse, varscan2
- CNR2 | c.468C>A p.I156= | Silent (SNP) | VAF 172/360 reads (48%) | catalogued as COSV65694937; called by muse, varscan2
- CSMD1 | c.1188G>A p.T396= (on ENST00000520002; = p.T395= on NM_033225.6) | Silent (SNP) | VAF 497/1080 reads (46%) | catalogued as rs754992588, COSV68173022; called by muse, varscan2
- PTPRS | c.1287G>A p.A429= | Silent (SNP) | VAF 130/266 reads (49%) | catalogued as rs1244320927, COSV53632368; called by muse, varscan2
- CTPS1 | c.1692-47G>T | Intron (SNP) | VAF 17/118 reads (14%) | called by muse, varscan2
- RUSF1 | c.1017-66G>A | Intron (SNP) | VAF 29/55 reads (53%) | catalogued as rs1304776294; called by muse, varscan2
